Somatic mutation profile of tumor specimen TARGET-20-PASAUN-09A (aliquot TARGET-20-PASAUN-09A-01D) from TARGET case TARGET-20-PASAUN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,595 days).
Specimen TARGET-20-PASAUN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f149e6f-da1d-499b-a5bc-d8fc4087bf3e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASAUN-14A (Bone Marrow Normal), aliquot TARGET-20-PASAUN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5abe4f9d-468a-4a8b-bda8-503813bfe5dc

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2035C>T p.R679C (on ENST00000460911 / NM_001203247.2; = p.R684C on NM_004456.5) | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs587783626, CM1110542, COSV57449598, COSV57463748; ClinVar: pathogenic; called by muse, mutect2, varscan2
